TARGET case TARGET-40-PALECC — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e03feed7-8deb-500e-bb1f-abad7d909047

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Age at index: 10 years; Vital status: Dead; Days to death: 754 days (2.1 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.0; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 10.0 years (3,661 days); Year of diagnosis: 2001; Metastasis at diagnosis: No Metastasis; Days to last follow up: 754 days (2.1 years).
   Treatment given: Protocol identifier: P9851.

Follow-up (2 entries)
- Days to follow up: 384 days (1.1 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 384 days (1.1 years); Days to first event: 384 days (1.1 years); First event: Relapse.
- Days to follow up: 754 days (2.1 years); Progression or recurrence: Yes; Progression or recurrence type: Local; Year of follow up: 2003.

Biospecimens (2 samples)
- Sample TARGET-40-PALECC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-PALECC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_20230709.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 754
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Arm/hand
- Specific tumor site: Arm NOS
- Primary site progression: Yes
- Site of initial relapse: Lung

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-PALECC-01A:
- Specimen Type: Frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 90
- % Non Tumor Nuclei: Top from Biopsy: 10
- % Cellular Tumor: Top from Biopsy: 45
- % Normal: Top from Biopsy: 3
- % Stroma: Top from Biopsy: 17
- % Necrosis: Top from Biopsy: 35
- % Tumor Nuclei: Bottom from Biopsy: 90
- % Non Tumor Nuclei: Bottom from Biopsy: 10
- % Cellular Tumor: Bottom from Biopsy: 25
- % Normal: Bottom from Biopsy: 1
- % Stroma: Bottom from Biopsy: 8
- % Necrosis: Bottom from Biopsy: 66
- PASS/FAIL: fail
